Somatic mutation profile of tumor specimen ALCH-AF1H-TTR1-A (aliquot ALCH-AF1H-TTR1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-AF1H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,192 days).
Specimen ALCH-AF1H-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d51dcc6-3988-4aab-a691-33e744ec476f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF1H-NB1-A (Blood Derived Normal), aliquot ALCH-AF1H-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04a75a75-8fed-425f-baeb-036597008f77

The open-access MAF lists 133 somatic variants for this specimen: 86 protein-altering or splice-affecting, 31 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 31, Intron 5, RNA 5, 3'UTR 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, 5'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 422/893 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 79/133 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691043, CM115637, COSV52672812, COSV52700410; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51074613; called by muse, mutect2, varscan2
- AGMO | c.573A>T p.Q191H | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs747881131; called by muse, varscan2
- CCDC27 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs560903163, COSV53899839; called by muse, mutect2, varscan2
- CNTNAP5 | c.2492A>G p.N831S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV70483885; called by muse, mutect2, varscan2
- CTAGE1 | c.942T>G p.D314E | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.121); catalogued as rs1196241165; called by muse, mutect2
- DPF1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV62792826, COSV62793491; called by muse, mutect2, varscan2
- GLI1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs369128119; called by muse, mutect2
- GOLGA8H | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1433661396; called by muse, mutect2
- GRAMD1B | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV59204338; called by muse, mutect2
- GSTM2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs1247954722; called by muse, mutect2, varscan2
- INSYN2B | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV56964405; called by muse, mutect2, varscan2
- KLF5 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66614238; called by muse, mutect2, varscan2
- KLHL18 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs747268928; called by muse, mutect2, varscan2
- KPRP | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs776972984, COSV64220986; called by muse, mutect2, varscan2
- LILRB5 | c.1197C>G p.I399M | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV60255045; called by muse, mutect2, varscan2
- OCLN | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 84/459 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1267876764; called by muse, mutect2, varscan2
- OR14I1 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1169080376; called by muse, mutect2
- PACSIN1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs758224914, COSV99762837; called by muse, mutect2, varscan2
- PCDHB3 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50568542; called by muse, mutect2, varscan2
- PDE6B | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201593198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIWIL3 | c.2344C>G p.P782A | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.893); catalogued as COSV59993929; called by muse, mutect2, varscan2
- POU6F2 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 75/444 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs1320590589; called by muse, mutect2, varscan2
- PRSS3 | c.167C>T p.P56L (on ENST00000361005 / NM_007343.4; = p.P164L on NM_002771.3) | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs898973804; called by muse, mutect2
- R3HDM1 | c.1924-1G>C p.X642_splice | Splice Site (SNP) | VAF 35/231 reads (15%) | catalogued as COSV51525052; called by muse, mutect2, varscan2
- RBFOX1 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 196/409 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV100300797; called by muse, mutect2, varscan2
- RYR2 | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 67/554 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63664965, COSV63720100; called by muse, mutect2, varscan2
- SKAP2 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 54/559 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61727681; called by muse, mutect2, varscan2
- SPATA48 | c.505T>C p.W169R | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754420047; called by muse, mutect2
- STAB1 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs752284290, COSV104396328; called by muse, mutect2, varscan2
- STXBP3 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV64182088; called by muse, mutect2, varscan2
- SYNE2 | c.9076G>C p.E3026Q | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100646568, COSV59941318; called by muse, mutect2, varscan2
- SZT2 | c.5816G>A p.R1939Q (on ENST00000634258 / NM_001365999.1; = p.R1882Q on NM_015284.4) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs779576338, COSV65171732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF20 | c.4167G>C p.K1389N | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs370868872; called by muse, mutect2, varscan2
- ZNF292 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs374988651; called by muse, mutect2, varscan2
- AC127029.3 | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 73/485 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMOTL1 | c.2289A>G p.I763M | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- BIVM-ERCC5 | c.1945A>C p.S649R | Missense Mutation (SNP) | VAF 34/549 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- BIVM-ERCC5 | c.1946G>T p.S649I | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- BLMH | c.721A>T p.N241Y | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2
- C1orf198 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- C2orf73 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- CBLN4 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 179/456 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CENPF | c.2577C>G p.I859M | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CLCN2 | c.2348T>C p.V783A | Missense Mutation (SNP) | VAF 74/365 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CREB1 | c.678G>C p.Q226H (on ENST00000432329 / NM_134442.5; = p.Q212H on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- DCHS2 | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DDB2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 140/287 reads (49%) | called by muse, mutect2, varscan2
- DEK | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- EIF3E | c.952G>C p.V318L | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); called by muse, mutect2
- EYS | c.9125C>T p.A3042V (on ENST00000370621 / NM_001292009.1; = p.A3021V on NM_001142800.2) | Missense Mutation (SNP) | VAF 127/368 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- FLT3 | c.368+1G>T p.X123_splice | Splice Site (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- FSIP2 | c.7242A>C p.K2414N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- KDM6A | c.4162G>C p.D1388H | Missense Mutation (SNP) | VAF 79/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KMT2E | c.5085_5094del p.H1695Qfs*14 | Frame Shift Del (DEL) | VAF 33/167 reads (20%) | called by mutect2, pindel, varscan2
- LAMA1 | c.8074C>A p.P2692T | Missense Mutation (SNP) | VAF 126/213 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- LAMP2 | c.140A>C p.Q47P | Missense Mutation (SNP) | VAF 141/193 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MAGEB4 | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEC1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- MTMR2 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC4 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- NLRP8 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NYNRIN | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); called by muse, mutect2
- OTOA | c.1437G>T p.M479I (on ENST00000286149; = p.M465I on NM_144672.4) | Missense Mutation (SNP) | VAF 19/628 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHA12 | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PLCB1 | c.2975A>G p.Q992R | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.2674+3G>C | Splice Region (SNP) | VAF 81/194 reads (42%) | called by muse, mutect2, varscan2
- PRKCB | c.1568A>C p.D523A | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRU | c.4287C>A p.Y1429* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- RASGRP1 | c.47A>T p.H16L | Missense Mutation (SNP) | VAF 203/343 reads (59%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SDE2 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 118/961 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD1A | c.4810C>A p.Q1604K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC26A9 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 160/427 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SLC35D1 | c.990C>G p.I330M | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- SLX4 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SOX21 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 178/505 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- SPEG | c.9723C>A p.F3241L | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SSTR2 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR2 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TMEM232 | c.966G>C p.L322F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TOMM40 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.484); called by muse, mutect2
- TOP2B | c.1448del p.G483Efs*12 (on ENST00000264331 / NM_001330700.2; = p.G478Efs*12 on NM_001068.3) | Frame Shift Del (DEL) | VAF 72/168 reads (43%) | called by mutect2, pindel, varscan2
- TTN | c.13709A>T p.K4570M (on ENST00000591111; = p.K3643M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/244 reads (32%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBAC1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2
- VEGFB | c.375-7_375-2delinsGT p.X125_splice | Splice Site (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2*
- AANAT | c.414C>A p.I138= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1355634303; called by muse, mutect2
- C2orf16 | c.5916C>G p.P1972= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- CALCRL | c.1257G>A p.A419= | Silent (SNP) | VAF 46/242 reads (19%) | catalogued as rs146718835; called by muse, mutect2, varscan2
- CCT8L2 | c.900C>T p.D300= | Silent (SNP) | VAF 63/313 reads (20%) | catalogued as rs772533950, COSV63462162; called by muse, mutect2, varscan2
- CSMD2 | c.6000G>T p.L2000= | Silent (SNP) | VAF 68/276 reads (25%) | called by muse, mutect2, varscan2
- DERL1 | c.42C>T p.I14= | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- EFCAB5 | c.222A>T p.S74= | Silent (SNP) | VAF 13/61 reads (21%) | called by mutect2, varscan2
- FOXD3 | c.958C>T p.L320= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- HTR1B | c.501G>A p.A167= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs772064678, COSV64051452; called by muse, mutect2
- KHNYN | c.615A>G p.A205= | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as rs540170795; called by muse, mutect2, varscan2
- KIR3DL2 | c.111T>C p.T37= | Silent (SNP) | VAF 21/520 reads (4%) | called by muse, mutect2
- KLK1 | c.111C>A p.P37= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.3219G>C p.V1073= | Silent (SNP) | VAF 205/675 reads (30%) | called by muse, mutect2, varscan2
- MEIS1 | c.867G>T p.A289= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as COSV99715248; called by muse, mutect2, varscan2
- MRPL19 | c.354T>C p.R118= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- MUC7 | c.15G>A p.P5= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as rs765330448, COSV59217571; called by muse, mutect2, varscan2
- NOX4 | c.69C>A p.L23= | Silent (SNP) | VAF 120/253 reads (47%) | called by muse, mutect2, varscan2
- OR1N2 | c.654C>G p.V218= | Silent (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- OR2T1 | c.414G>A p.R138= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as COSV63542850; called by muse, mutect2
- PLXNA4 | c.1737G>T p.L579= | Silent (SNP) | VAF 114/221 reads (52%) | called by muse, mutect2, varscan2
- POU4F2 | c.1062G>A p.A354= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs367653245; called by muse, mutect2, varscan2
- PTOV1 | c.1026C>T p.I342= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs376020024; called by muse, mutect2, varscan2
- RAD54L2 | c.2523C>T p.C841= | Silent (SNP) | VAF 19/566 reads (3%) | called by muse, mutect2
- RNASEL | c.1785G>A p.T595= | Silent (SNP) | VAF 83/666 reads (12%) | catalogued as rs748847842, COSV62376976; called by muse, mutect2, varscan2
- SFXN3 | c.276G>C p.L92= | Silent (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1653C>T p.N551= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as rs374911541; called by muse, mutect2, varscan2
- SLC6A18 | c.1059G>C p.L353= | Silent (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.168T>A p.G56= | Silent (SNP) | VAF 97/289 reads (34%) | catalogued as COSV61789953; called by muse, mutect2, varscan2
- TBX3 | c.516G>A p.V172= | Silent (SNP) | VAF 264/497 reads (53%) | called by muse, mutect2, varscan2
- VANGL2 | c.750C>T p.V250= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs770088137; called by muse, mutect2, varscan2
- ZNF318 | c.3312G>A p.K1104= | Silent (SNP) | VAF 50/200 reads (25%) | called by muse, mutect2, varscan2
- AC114741.1 | n.448A>C | RNA (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- C7orf33 | c.-22A>G | 5'UTR (SNP) | VAF 14/460 reads (3%) | catalogued as rs1302687656; called by muse, mutect2
- FGF2 | c.*23C>G | 3'UTR (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- FHL1 | c.*310G>A | 3'UTR (SNP) | VAF 99/184 reads (54%) | called by muse, mutect2, varscan2
- GVINP1 | n.6801A>T | RNA (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.-11A>G | 5'UTR (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- LINC01559 | n.400+1277T>C | Intron (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- LINC02716 | n.423G>C | RNA (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- LRRC6 | c.10+61C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65642G>T | Intron (SNP) | VAF 56/185 reads (30%) | called by mutect2, varscan2
- PLXNB3 | c.46-640C>A | Intron (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128129065 A>G | 5'Flank (SNP) | VAF 143/347 reads (41%) | catalogued as rs1003447883; called by muse, mutect2, varscan2
- PTPN5 | c.1330-78C>A | Intron (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- SLC19A2 | c.*30A>T | 3'UTR (SNP) | VAF 44/494 reads (9%) | called by muse, mutect2
- SNORD116-14 | n.81G>A | RNA (SNP) | VAF 158/461 reads (34%) | catalogued as rs752130153; called by muse, mutect2, varscan2
- UGT2B27P | n.1560C>A | RNA (SNP) | VAF 46/255 reads (18%) | called by muse, mutect2, varscan2
